Somatic mutation profile of tumor specimen TARGET-20-PARCZL-09A (aliquot TARGET-20-PARCZL-09A-03D) from TARGET case TARGET-20-PARCZL, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 10.4 years (3,806 days).
Specimen TARGET-20-PARCZL-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4142d3ee-fc16-4c2f-882f-88bbabc182c6.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PARCZL-14A (Bone Marrow Normal), aliquot TARGET-20-PARCZL-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f2165547-9b35-4f74-b4fd-fe9b05e2ea87

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 99/246 reads (40%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PPP1R14C | c.449G>A p.R150Q | Missense Mutation (SNP) | VAF 71/212 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); catalogued as rs766379125, COSV100744829, COSV63173202; called by muse, mutect2, varscan2
- SMC3 | c.1142G>A p.R381Q | Missense Mutation (SNP) | VAF 65/162 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV62419567; called by muse, mutect2, varscan2
